EXCEPTIONAL_RESPONDERS case ER-B0GF — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81e472aa-4a3b-490c-8114-1e9ec984c5ac

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: metastasis; Age at diagnosis: 72.1 years (26,320 days); Year of diagnosis: 2013; AJCC clinical stage: Stage IV; Prior malignancy: yes; Days to last follow up: 1,342 days (3.7 years); Days to best overall response: 850 days (2.3 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 241 days; Days to treatment end: 458 days (1.3 years).
   Treatment given: Therapeutic agents: Irinotecan; Days to treatment start: 255 days; Days to treatment end: 255 days.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 696 days (1.9 years); Days to treatment end: 795 days (2.2 years).
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 696 days (1.9 years); Days to treatment end: 738 days (2.0 years).

Follow-up (1 entry)
- Days to follow up: 1,342 days (3.7 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,342 days (3.7 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GF-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GF-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0GF-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GF-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 25; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
